Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5SG, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5SG-06A (Metastatic).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: LYMPH NODE CHECKLIST

Specimen type: Tumor excision (ex: Hysterectomy)

Tumor site: Lymph node, axillary

Tumor size (in cm): 3 x 3 x 0.5cm

Histologic type: Metastatic neoplasm, malignant melanoma (ex: Squamous cell carcinoma)

Histologic grade: Not specified

Tumor extent: Not specified

Lymph nodes: 1/1

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment:

If yes, type of treatment seen:

Severity of treatment effect:

Comments: None

ICD-O-3
Melanoma, malignant NOS
8720/3
Site: Lymph Node, axilla
C77.3
JW 2/18/13

Diagnostic Discrepancy		✓
ICDPA Discrepancy		✓
Case is (clinical) Melanoma	✓	
Case is (clinical) KMF	✓	

Source: NCI Genomic Data Commons file 1e31f66d-6a35-4e78-8eab-fe51ac29d550 (TCGA-EB-A5SG.67845F3E-781C-4AFD-BF48-E3C533AECA4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).